Gene-level copy-number profile of tumor specimen TARGET-10-PAUBCT-09A from TARGET case TARGET-10-PAUBCT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.0 years (4,757 days).
Specimen TARGET-10-PAUBCT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.c0d798cc-eea3-5dc3-bd0b-dbe6d6a93bc2.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PAUBCT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate.
https://portal.gdc.cancer.gov/files/07896e12-f9e1-419b-bc41-65b9aa215f42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,445; copy number 1: 916; copy number 2: 56,620; copy number 3: 206; copy number 4: 39.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,708,125–29,708,547, 1 gene: ZDHHC20P1.
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.
- chr7:142,615,716–142,793,368, 29 genes: TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr11:18,933,813–18,939,721, 2 genes: MRGPRX1, AC023078.1.
- chr14:22,163,238–22,482,959, 21 genes (within-gene range 0–2): TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr18:59,929,226–59,973,207, 3 genes: AC107990.1, NFE2L3P1, RN7SL342P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 882. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
